Somatic mutation profile of tumor specimen TCGA-CR-6471-01A (aliquot TCGA-CR-6471-01A-11D-1870-08) from TCGA case TCGA-CR-6471, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 58.4 years (21,315 days).
Specimen TCGA-CR-6471-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b41f6ff-8a70-4a29-aeaf-04f700b69898.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CR-6471-10A (Blood Derived Normal), aliquot TCGA-CR-6471-10A-01D-1870-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b63d2e5c-f299-48e3-b060-689d462eb375

The open-access MAF lists 141 somatic variants for this specimen: 102 protein-altering or splice-affecting, 37 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 90, Silent 37, Nonsense Mutation 6, Frame Shift Ins 3, Frame Shift Del 2, Intron 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB6 | c.1123C>T p.R375W | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764893806, CM1211185, COSV54693138; ClinVar: pathogenic; called by muse, mutect2
- DNMT3B | c.2519G>A p.R840Q | Missense Mutation (SNP) | VAF 37/152 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs121908946, CM021983, COSV99141428; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 16/84 reads (19%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3127A>G p.M1043V | Missense Mutation (SNP) | VAF 14/60 reads (23%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs1057519936, COSV55879858, COSV55890961; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SMAD2 | c.544C>T p.R182* | Nonsense Mutation (SNP) | VAF 13/62 reads (21%) | hotspot (GDC flag); catalogued as COSV50993252; called by muse, mutect2, varscan2
- AL669918.1 | c.2369C>T p.T790I | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.237); catalogued as rs943827909, COSV101441045; called by muse, mutect2, varscan2
- ARHGAP15 | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs781224062, COSV54476221; called by muse, mutect2, varscan2
- ASAH2B | c.22A>G p.M8V | Missense Mutation (SNP) | VAF 69/272 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.328); catalogued as COSV99485890; called by muse, mutect2, varscan2
- ASAP1 | c.1875A>C p.Q625H | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as COSV100727260; called by muse, mutect2, varscan2
- ATRIP | c.1349C>T p.P450L | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as rs766789931, COSV99604010; called by muse, mutect2, varscan2
- B3GNT7 | c.208G>T p.A70S | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.7); PolyPhen benign (0.015); catalogued as COSV55007286; called by muse, mutect2, varscan2
- CCDC125 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 55/107 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101143593; called by muse, mutect2, varscan2
- CD226 | c.582A>T p.Q194H | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.096); catalogued as COSV99711106; called by muse, mutect2, varscan2
- CEP290 | c.4284A>G p.I1428M | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.216); catalogued as COSV100468699; called by muse, mutect2
- CETN1 | c.199G>C p.E67Q | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.492); catalogued as COSV100511317, COSV59121082; called by muse, mutect2, varscan2
- CPT2 | c.497T>A p.L166H | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53759599, COSV99598133; called by muse, mutect2, varscan2
- CSMD1 | c.6656G>A p.G2219D (on ENST00000520002; = p.G2218D on NM_033225.6) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV100147659; called by muse, mutect2, varscan2
- CXXC5 | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 89/214 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs756512474, COSV100210710; called by muse, mutect2, varscan2
- DCAF6 | c.1942G>A p.D648N (on ENST00000312263 / NM_001349778.1; = p.D668N on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.035); catalogued as COSV100394286; called by muse, mutect2, varscan2
- DCHS1 | c.3122C>A p.A1041E | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.161); catalogued as rs1453133962, COSV100202024; called by muse, mutect2, varscan2
- DHX15 | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs754378482, COSV61027175; called by muse, mutect2, varscan2
- DNAH5 | c.5869C>T p.P1957S | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54252350, COSV99449632; called by muse, mutect2, varscan2
- DOCK1 | c.4579A>T p.N1527Y | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99729555; called by muse, mutect2
- DPP10 | c.928C>T p.P310S | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.953); catalogued as COSV59745136; called by muse, mutect2
- EP300 | c.4337A>G p.Y1446C | Missense Mutation (SNP) | VAF 54/133 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54349906, COSV99608501; called by muse, mutect2, varscan2
- EPHA7 | c.893C>A p.T298N | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.066); catalogued as COSV100993676; called by muse, mutect2, varscan2
- FAM184A | c.1318C>A p.L440I | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.031); catalogued as COSV100137786; called by muse, mutect2, varscan2
- FAM71A | c.1413T>G p.D471E | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV99674600; called by muse, mutect2, varscan2
- FAM83B | c.352G>A p.G118S | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.015); catalogued as rs779324231, COSV60922890; called by muse, mutect2, varscan2
- FUT5 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.304); catalogued as rs866925823, COSV99398744; called by muse, mutect2, varscan2
- GCK | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.648); catalogued as rs104894005, CM920307, CM930304, COSV100357186; called by muse, mutect2, varscan2
- GNPTAB | c.3241C>T p.P1081S | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs375783746, COSV73418401; called by muse, mutect2, varscan2
- GOLGA1 | c.1882C>T p.Q628* | Nonsense Mutation (SNP) | VAF 45/322 reads (14%) | catalogued as COSV100764448; called by muse, mutect2, varscan2
- GOLGA1 | c.1881G>T p.E627D | Missense Mutation (SNP) | VAF 44/320 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100764449; called by muse, mutect2, varscan2
- GPX6 | c.449C>A p.T150N | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); catalogued as COSV100724833; called by muse, mutect2, varscan2
- GRIK5 | c.1350G>A p.M450I | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.733); catalogued as rs747140762, COSV99490534; called by muse, mutect2, varscan2
- HELQ | c.1216A>G p.I406V | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs372496040; called by muse, mutect2, varscan2
- IFNA21 | c.317A>C p.E106A | Missense Mutation (SNP) | VAF 48/231 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV101207423; called by muse, mutect2, varscan2
- IGSF3 | c.1682C>G p.S561C (on ENST00000369486 / NM_001007237.3; = p.S581C on NM_001542.4) | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59585375, COSV59596206; called by muse, mutect2, varscan2
- IGSF9 | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs755384018, COSV100829623, COSV63639937; called by muse, mutect2, varscan2
- IMPDH1 | c.665C>A p.A222D (on ENST00000470772 / NM_001142573.2; = p.A308D on NM_000883.4) | Missense Mutation (SNP) | VAF 38/163 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100118674; called by muse, mutect2, varscan2
- INPP4B | c.2495G>T p.R832L | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53727314, COSV99524601; called by muse, mutect2, varscan2
- IQCN | c.166C>T p.H56Y | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.329); catalogued as COSV101148624; called by muse, mutect2, varscan2
- KCNE4 | c.277G>T p.V93F | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99918957; called by muse, mutect2, varscan2
- KCNT2 | c.1621C>T p.R541* | Nonsense Mutation (SNP) | VAF 24/82 reads (29%) | catalogued as rs528303127, COSV54092992; called by muse, mutect2, varscan2
- KIF1C | c.2693C>T p.A898V | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV100297130; called by muse, mutect2, varscan2
- KRBA2 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 47/179 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.055); catalogued as rs781717920, COSV100497660; called by muse, mutect2, varscan2
- KRTAP5-3 | c.175T>C p.S59P | Missense Mutation (SNP) | VAF 86/295 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.041); catalogued as COSV101294511; called by muse, mutect2, varscan2
- LIN28B | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 44/168 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61494418; called by muse, mutect2, varscan2
- LTBP1 | c.3665A>G p.E1222G (on ENST00000404816 / NM_206943.4; = p.E896G on NM_000627.4) | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.297); catalogued as rs996633642, COSV99698269; called by muse, mutect2, varscan2
- MARK1 | c.1060A>G p.I354V | Missense Mutation (SNP) | VAF 89/347 reads (26%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV100857230; called by muse, mutect2, varscan2
- MARS2 | c.1442G>A p.R481Q | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as COSV56571121; called by muse, mutect2, varscan2
- METTL21C | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs749722813, COSV99940035; called by muse, mutect2, varscan2
- MFSD2A | c.289A>G p.I97V (on ENST00000372809 / NM_001136493.3; = p.I84V on NM_032793.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/224 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.147); catalogued as COSV100861689; called by muse, mutect2, varscan2
- MIB1 | c.1306G>C p.V436L | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.685); catalogued as COSV99838775; called by muse, mutect2, varscan2
- MYH6 | c.3155G>A p.R1052Q | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750020902, COSV62448329; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO18A | c.4383G>A p.R1461= | Splice Region (SNP) | VAF 4/17 reads (24%) | catalogued as COSV100572267; called by muse, mutect2
- OR2L13 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 69/310 reads (22%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.575); catalogued as rs751292468, COSV63553896; called by muse, mutect2, varscan2
- OR5H6 | c.746G>A p.G249E (on ENST00000642105; = p.G233E on NM_001005479.2) | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs1399310499, COSV67351483; called by muse, mutect2, varscan2
- OSBPL6 | c.574A>T p.R192* | Nonsense Mutation (SNP) | VAF 27/101 reads (27%) | catalogued as COSV99507417; called by muse, mutect2, varscan2
- PCDHA12 | c.1244G>A p.R415H | Missense Mutation (SNP) | VAF 65/321 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.913); catalogued as COSV56532425; called by muse, mutect2, varscan2
- PDGFRA | c.1672C>T p.R558C | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs765680542, COSV57264462; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPP1R9A | c.2601C>A p.D867E | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV99195584; called by muse, mutect2, varscan2
- PTPRH | c.1342G>A p.G448R | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs373526913, COSV99671317; called by muse, mutect2, varscan2
- RAB40C | c.119A>G p.E40G | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.686); catalogued as COSV99937732; called by muse, mutect2
- RBKS | c.187G>T p.A63S | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.502); catalogued as COSV100142157; called by muse, mutect2, varscan2
- RSPH14 | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs756184087, COSV99320749; called by muse, mutect2, varscan2
- RTF1 | c.602A>G p.E201G | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101047824, COSV67478521; called by muse, mutect2, varscan2
- RTN4IP1 | c.1162C>T p.R388* | Nonsense Mutation (SNP) | VAF 23/126 reads (18%) | catalogued as rs764393326, COSV100954183; called by muse, mutect2, varscan2
- SERPINE2 | c.13C>T p.L5F | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51455937, COSV99296702; called by muse, mutect2, varscan2
- SGCD | c.752C>T p.T251M (on ENST00000435422 / NM_001128209.2; = p.T252M on NM_000337.5) | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs199520526; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SH2D4B | c.1268A>C p.D423A (on ENST00000646907; = p.G348= on NM_207372.2) | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV100213878; called by muse, mutect2, varscan2
- SIM1 | c.1298C>T p.S433L | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.991); catalogued as COSV53489214; called by muse, mutect2, varscan2
- SLC15A3 | c.1033C>G p.H345D | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV99135162; called by muse, mutect2, varscan2
- SLC4A10 | c.338T>A p.I113N | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.359); catalogued as COSV99764008; called by muse, mutect2, varscan2
- SNAP25 | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.732); catalogued as rs374115269; called by muse, mutect2, varscan2
- SNAP47 | c.311A>T p.E104V | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100248141; called by muse, mutect2, varscan2
- SPPL3 | c.739C>G p.R247G | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.361); catalogued as COSV100793615; called by muse, mutect2, varscan2
- STK10 | c.1384G>A p.G462R | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.019); catalogued as COSV99451478; called by muse, mutect2, varscan2
- STK10 | c.560A>G p.Q187R | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99451482; called by muse, mutect2, varscan2
- TBC1D32 | c.1651G>T p.G551C | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as COSV99250281; called by muse, mutect2, varscan2
- TEX13A | c.182G>A p.S61N | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.092); catalogued as COSV100781265; called by muse, mutect2, varscan2
- TMEM72 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs373669899; called by muse, mutect2, varscan2
- TRIM71 | c.1219A>C p.N407H | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV101070431; called by muse, mutect2, varscan2
- TRPC5 | c.229G>T p.A77S | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as COSV99460871; called by muse, mutect2, varscan2
- TRPV4 | c.671G>T p.R224M | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV99924689; called by muse, mutect2, varscan2
- TTN | c.47198T>A p.I15733N (on ENST00000591111; = p.I8309N on NM_003319.4) | Missense Mutation (SNP) | VAF 32/164 reads (20%) | PolyPhen possibly damaging (0.542); catalogued as COSV100611966; called by muse, mutect2, varscan2
- UBR5 | c.7330G>T p.E2444* | Nonsense Mutation (SNP) | VAF 30/164 reads (18%) | catalogued as COSV99640816; called by muse, mutect2, varscan2
- UTP20 | c.5314A>G p.I1772V | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs751752396, COSV99881607; called by muse, mutect2, varscan2
- WDR19 | c.1015C>G p.Q339E | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV56465214, COSV99975480; called by muse, mutect2, varscan2
- XDH | c.3711del p.I1238Lfs*54 | Frame Shift Del (DEL) | VAF 40/198 reads (20%) | catalogued as COSV101052227; called by mutect2, pindel, varscan2
- ZBTB8A | c.764C>T p.S255F | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as COSV100331360; called by muse, mutect2, varscan2
- ZC3H4 | c.3067G>A p.A1023T | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs771929582, COSV99452278; called by muse, mutect2, varscan2
- ZNF407 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.878); catalogued as rs760068295, COSV55270449, COSV99995679; called by muse, mutect2, varscan2
- ZNF460 | c.1311G>T p.R437S | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV100828078, COSV64415268; called by muse, mutect2, varscan2
- ZNF572 | c.727C>A p.P243T | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100073952; called by muse, mutect2, varscan2
- ZNF594 | c.1496G>A p.R499Q | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs553767305, COSV68386285; called by muse, mutect2, varscan2
- ZNF99 | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV68055685; called by muse, mutect2, varscan2
- HUWE1 | c.7520dup p.S2508Ifs*81 | Frame Shift Ins (INS) | VAF 19/38 reads (50%) | called by mutect2, pindel, varscan2
- MBTPS1 | c.1328dup p.Q444Afs*17 | Frame Shift Ins (INS) | VAF 15/60 reads (25%) | called by mutect2, pindel, varscan2
- PCDHGA9 | c.1398_1399del p.G468Yfs*10 | Frame Shift Del (DEL) | VAF 15/117 reads (13%) | called by mutect2, pindel, varscan2
- RFX7 | c.2049dup p.G684Wfs*7 (on ENST00000559447 / NM_001368074.1; = p.G781Wfs*7 on NM_022841.7 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 22/106 reads (21%) | called by mutect2, pindel, varscan2
- ALB | c.1626G>A p.E542= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as COSV55735807; called by muse, mutect2, varscan2
- BDH2 | c.57C>G p.G19= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV99600685; called by muse, mutect2, varscan2
- CARD11 | c.3351C>T p.Y1117= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as rs771697547, COSV67797018; called by muse, mutect2, varscan2
- CLEC16A | c.1371G>A p.E457= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV101278027; called by muse, mutect2, varscan2
- CPN2 | c.1449C>T p.Y483= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as rs777787446, COSV100103089; called by mutect2, varscan2
- CREBBP | c.5112C>G p.V1704= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as rs1320546478, COSV99270001; called by muse, mutect2, varscan2
- DOCK9 | c.5073C>A p.I1691= (on ENST00000376460 / NM_001366676.2; = p.I1692= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 37/165 reads (22%) | catalogued as COSV100239248; called by muse, mutect2, varscan2
- EPHA8 | c.1782C>T p.F594= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as rs750902137, COSV51272084; called by muse, mutect2, varscan2
- EXO1 | c.495A>G p.Q165= | Silent (SNP) | VAF 23/104 reads (22%) | catalogued as COSV100799824; called by muse, mutect2, varscan2
- GPAA1 | c.1104C>T p.F368= | Silent (SNP) | VAF 95/195 reads (49%) | catalogued as rs371058225; called by muse, mutect2, varscan2
- GRM4 | c.750C>A p.I250= | Silent (SNP) | VAF 27/60 reads (45%) | catalogued as COSV100946179; called by muse, mutect2, varscan2
- IGLC7 | c.168C>T p.T56= | Silent (SNP) | VAF 8/63 reads (13%) | called by muse, mutect2
- IRX2 | c.1197C>T p.N399= | Silent (SNP) | VAF 24/102 reads (24%) | catalogued as rs749189949, COSV57410486; called by muse, mutect2, varscan2
- KIAA1522 | c.720C>G p.V240= (on ENST00000373480 / NM_001198972.2; = p.V299= on NM_020888.3) | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as COSV53862226; called by muse, mutect2, varscan2
- LPP | c.370T>C p.L124= | Silent (SNP) | VAF 45/155 reads (29%) | catalogued as COSV100447183; called by muse, mutect2, varscan2
- MFHAS1 | c.1155C>T p.C385= | Silent (SNP) | VAF 23/44 reads (52%) | catalogued as COSV99359580; called by muse, mutect2, varscan2
- MRC1 | c.765G>A p.L255= | Silent (SNP) | VAF 38/137 reads (28%) | catalogued as COSV100509597; called by muse, mutect2, varscan2
- NUDT12 | c.162A>C p.A54= | Silent (SNP) | VAF 16/141 reads (11%) | catalogued as COSV100048192; called by muse, mutect2, varscan2
- OR5H2 | c.216C>G p.A72= | Silent (SNP) | VAF 55/275 reads (20%) | catalogued as COSV100788728; called by muse, mutect2, varscan2
- PAQR8 | c.765C>T p.F255= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as COSV62442638; called by muse, mutect2, varscan2
- PCDHA7 | c.1815G>T p.A605= | Silent (SNP) | VAF 33/128 reads (26%) | catalogued as COSV100971476; called by muse, mutect2, varscan2
- PUS7 | c.1816C>T p.L606= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as COSV100708543; called by muse, mutect2, varscan2
- RELN | c.2499G>A p.K833= | Silent (SNP) | VAF 18/108 reads (17%) | catalogued as COSV100633700; called by muse, mutect2, varscan2
- REXO5 | c.1863C>G p.L621= | Silent (SNP) | VAF 32/132 reads (24%) | catalogued as COSV99759181; called by muse, mutect2, varscan2
- SETD1A | c.2955G>A p.E985= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs1257608466, COSV99352950; called by muse, mutect2, varscan2
- SETD2 | c.2568C>T p.I856= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as rs775705122, COSV100338971; called by muse, mutect2, varscan2
- SH3PXD2B | c.1032G>A p.Q344= | Silent (SNP) | VAF 13/105 reads (12%) | catalogued as COSV100287976; called by muse, mutect2, varscan2
- SIRPB2 | c.993C>A p.A331= | Silent (SNP) | VAF 39/162 reads (24%) | catalogued as COSV100708530; called by muse, mutect2, varscan2
- SLC6A13 | c.1650C>T p.L550= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV100569918; called by muse, mutect2, varscan2
- SMCHD1 | c.3237A>G p.R1079= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as rs750602228, COSV99861638; called by muse, mutect2
- SUSD5 | c.162G>A p.L54= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV100535122; called by muse, mutect2
- TAS2R7 | c.180C>T p.C60= | Silent (SNP) | VAF 27/96 reads (28%) | catalogued as rs566735298, COSV53691392; called by muse, mutect2, varscan2
- VPS8 | c.3738G>T p.S1246= (on ENST00000625842 / NM_001349294.1; = p.S1244= on NM_015303.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as COSV99802118; called by muse, mutect2, varscan2
- WASF3 | c.1245G>A p.S415= | Silent (SNP) | VAF 28/129 reads (22%) | catalogued as rs148684191; called by muse, mutect2, varscan2
- ZKSCAN2 | c.1431C>T p.I477= | Silent (SNP) | VAF 32/129 reads (25%) | catalogued as rs149172025, COSV60158802; called by muse, mutect2, varscan2
- ZNF440 | c.510A>G p.K170= | Silent (SNP) | VAF 55/159 reads (35%) | catalogued as COSV100407532; called by muse, mutect2, varscan2
- ZNF443 | c.1890C>T p.S630= | Silent (SNP) | VAF 27/162 reads (17%) | catalogued as COSV100042144; called by muse, varscan2
- MLLT10 | c.240+17798G>T | Intron (SNP) | VAF 10/38 reads (26%) | catalogued as COSV100308104; called by muse, mutect2, varscan2
- PPP1R9A | c.2757+564C>T | Intron (SNP) | VAF 21/56 reads (38%) | catalogued as rs761306153, COSV99195591; called by muse, mutect2, varscan2
